Somatic mutation profile of tumor specimen BA2400D (aliquot aq-BA2400D) from BEATAML1.0 case 2426, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.8 years (16,348 days).
Specimen BA2400D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f569e34-1465-4d74-a3ce-7d3482559b1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2115D (Solid Tissue Normal), aliquot aq-BA2115D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b38e110-df9f-4edc-95cc-46de74fc5536

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Intron 2, Missense Mutation 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC144A | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100501951; called by muse, mutect2, varscan2
- NLRP12 | c.2585+1G>A p.X862_splice | Splice Site (SNP) | VAF 68/184 reads (37%) | catalogued as rs762901830; called by muse, mutect2, varscan2
- TALDO1 | c.462G>A p.K154= | Splice Region (SNP) | VAF 36/87 reads (41%) | catalogued as rs764934737; called by muse, mutect2, varscan2
- ZNF780B | c.851A>G p.K284R | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM13A | c.864G>A p.E288= | Silent (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3735T>C p.G1245= | Silent (SNP) | VAF 81/221 reads (37%) | called by muse, mutect2, varscan2
- SLC17A4 | c.741T>C p.F247= | Silent (SNP) | VAF 60/164 reads (37%) | called by muse, mutect2, varscan2
- GSTZ1 | c.474+18C>T | Intron (SNP) | VAF 17/35 reads (49%) | catalogued as rs1326766758; called by muse, mutect2, varscan2
- TADA3 | c.1107-997G>A | Intron (SNP) | VAF 48/150 reads (32%) | catalogued as rs915761244; called by muse, mutect2, varscan2
